CPTAC case C3N-01368 — Brain — Gliomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Gliomas; Primary site: Brain. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/10547ce0-4d20-406f-90e2-88dc483fe81f

Demographics
Sex at birth: male; Race: white; Year of birth: 1951; Vital status: Dead; Days to death: 245 days; Year of death: 2017; Country of birth: Poland.

Diagnoses (1)
1. Glioblastoma: ICD-O-3 morphology code: 9440/3; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Frontal lobe; Age at diagnosis: 66.0 years (24,115 days); Year of diagnosis: 2017; Last known disease status: With tumor; Days to last known disease status: 245 days; Progression or recurrence: yes; Days to recurrence: 63 days; Days to last follow up: 245 days.
   Pathology details: Greatest tumor dimension: 3 cm.

Follow-up (2 entries)
- Days to follow up: 245 days; Disease response: With Tumor; Karnofsky performance status: 60; ECOG performance status: 2.
- Days to follow up: 245 days; Disease response: Progressive Disease; Progression or recurrence: Yes; Days to recurrence: 63 days; Karnofsky performance status: 60; ECOG performance status: 2.

Other clinical attributes
- Weight: 90 kg; Height: 180 cm; BMI: 27.78.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-01368-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 190 mg.
- Sample C3N-01368-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Frontal Lobe; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -22 days; Initial weight: 289 mg; Time between excision and freezing: 6 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-01368-23: Section location: Frontal Lobe; Percent tumor nuclei: 85; Percent necrosis: 5.
- Sample C3N-01368-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -22 days; Method of sample procurement: Blood Draw.
